CCDI case PBCBMZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6e3e8376-b555-4cd5-a112-266e2e675a02

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.2 years (4,467 days).

Biospecimens (3 samples)
- Sample 0DNWJE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNWJM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNWKS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
